Somatic mutation profile of tumor specimen 0DB6U1 from CCDI case PBBIZK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.6 years (933 days).
Specimen 0DB6U1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe1b7d1e-3ab7-47dc-bf8d-4da443cc7fba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB6TZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4806b33-7f99-47a5-a81b-1070153a3e52

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COBL | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 64/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs765121031; called by muse, mutect2, varscan2
- DCHS2 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 46/726 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59719249; called by muse, mutect2
- GLP2R | c.1250G>C p.R417P | Missense Mutation (SNP) | VAF 110/698 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52325804; called by muse, mutect2
- CDKN2C | c.420_421insAAACGCC p.C141Kfs*4 | Frame Shift Ins (INS) | VAF 49/314 reads (16%) | called by mutect2, varscan2
- PRC1 | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 66/439 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLOD2 | c.1128-47_1128-34del | Intron (DEL) | VAF 82/194 reads (42%) | called by mutect2, varscan2
- RND3 | c.349-49G>A | Intron (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
